Surgical pathology report (de-identified scan), TCGA case TCGA-06-1804, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1804-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

TCGA-06-1804

=====

CLINICAL HISTORY

Right frontal brain lesion

OPERATIVE DIAGNOSES

Right frontal brain lesion

Operation/Specimen: A: Brain tumor, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right frontal tumor, excision biopsies: Anaplastic oligodendroglioma (see comment).

COMMENT

Sections show an infiltrating glial tumor. Frequent mitotic figures are present as is necrosis. Tumor nuclei are mostly round to oval and many show nucleoli. In a few areas the cells more closely resemble neoplastic astrocytes. Other areas show mucinous pools or distinct microcystic architecture. The infiltrating tumor cells show prominent perineuronal satellitosis and perivascular spread. Some areas of the tumor show backgroundropy myelin. Many of these features are characteristic of oligodendroglial tumors. Occasional tumor cells are GFAP positive. GFAP positive reactive astrocytes are present. The tumor cells are CD20 and CD3 negative. NeuN highlights cortical neurons and perhaps a few tumor cell nuclei. Alcian blue is noncontributory.

The tumor shows demonstrates moderate p53 staining and the Ki-67 labeling index is approximately 35%.

This tumor shows distinct oligodendroglial and to a lesser extent astrocytic features, including astrocytic gemistocytes. The latter observation is complicated by the presence of numerous reactive astrocytes and some oligodendroglial mini-gemistocytes.

The differential diagnosis includes anaplastic oligodendroglioma or anaplastic oligoastrocytoma (WHO Grade III) and glioblastoma with an oligodendroglial component (WHO Grade IV). The patient's corresponding slides were also reviewed. Clinical correlation is necessary.

MGMT promoter methylation and EGFRvIII assays are pending and the results, which will be reported in procedure addenda, may help guide appropriate therapy.

1p19q LOH testing is recommended.

[page 2 of 4]
PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on paraffin tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: are D1S1592, D1S468, D1S1612, D1S496, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from paraffin tumor block and a corresponding blood specimen.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

Requested by:

[page 3 of 4]
first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p a 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

TCGA-06-1804

INTRA-OPERATIVE CONSULTATION

A. Brain, right frontal tumor, excision biopsy: High-grade glioma. Frozen section and smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GL 3 DESCRIPTION

A. Received fresh are fragments of soft tan tissue, 0.8 x 0.6 x 0.4 cm in aggregate. Samples are used for frozen sections and smears. The frozen residual is submitted in A1 and the unfrozen tissue is submitted in A2. [REDACTED]

B. Received fresh for permanent sections are fragments of soft tan tissue, 1.5 x 1.0 x 0.4 cm in aggregate. Submitted in toto in B1-B2. [REDACTED]

ICD-9(s):
191.9 191.9

Histo Data

Part A: Brain tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
TPS H/E x 1	(none)	[REDACTED]	

Part B: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
A1 Blue 2.5 x 1	1	[REDACTED]	

Requested by:

[page 4 of 4]
[REDACTED]

L26-DA x 1	1
mCD3-DA x 1	1
EGFR-curls x 1	1
m P-DA x 1	1
H, x 1	1
MGMT-curls x 1	1
MIB1-DA x 1	1
NeuN x 1	1
P53DO7 x 1	1
Rct 1 H/E x 1	1
H/E x 1	2

For EGFRvIII

[REDACTED] TCGA-06-1804

*** End of Report ***

Source: NCI Genomic Data Commons file 4fa3e195-5f27-49af-9d49-e7d6bdf040b5 (TCGA-06-1804.136737BF-4365-470B-A34A-3C578B041A71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).